Somatic mutation profile of tumor specimen MMRF_1365_1_BM_CD138pos (aliquot MMRF_1365_1_BM_CD138pos_T1_KAS5U_L01211) from MMRF case MMRF_1365, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.2 years (23,822 days).
Specimen MMRF_1365_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c63322c8-cf23-434b-9a22-948a51f46ab5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1365_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1365_1_PB_Whole_C2_KAS5U_L01222; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ff0fd44-3719-4df3-b256-5c2b9ad81e3b

The open-access MAF lists 78 somatic variants for this specimen: 34 protein-altering or splice-affecting, 15 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, 3'UTR 20, Silent 15, Intron 5, Frame Shift Del 3, RNA 2, 5'UTR 1, Splice Region 1, 3'Flank 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 23/46 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs121913238, COSV55502066, COSV55502677; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ELMO2 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV51681015; called by muse, mutect2, varscan2
- HPCAL4 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV65716092; called by muse, mutect2
- IGLV1-40 | c.142A>G p.I48V | Missense Mutation (SNP) | VAF 32/32 reads (100%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.047); catalogued as rs187953594; called by muse, varscan2
- IGLV4-60 | c.200A>C p.Y67S | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as rs374883744; called by muse, varscan2
- LIPC | c.273G>A p.S91= | Splice Region (SNP) | VAF 6/40 reads (15%) | catalogued as rs143786281; called by mutect2, varscan2
- NHLRC4 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); catalogued as rs778919538; called by muse, mutect2, varscan2
- PACRG | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376427225, COSV61307864; called by muse, mutect2, varscan2
- PON2 | c.874G>A p.V292M | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs773638997, COSV56001587; called by muse, mutect2, varscan2
- RB1 | c.2084T>G p.M695R | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs727504122, COSV57297587, COSV57315806; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH2D4B | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs778559693; called by muse, mutect2, varscan2
- STAG2 | c.3224C>G p.S1075* | Nonsense Mutation (SNP) | VAF 25/28 reads (89%) | catalogued as COSV54374282; called by muse, mutect2
- TCERG1L | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs557402004, COSV64046711; called by muse, mutect2, varscan2
- TNNI3K | c.1930A>G p.I644V | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs765917828; called by muse, mutect2, varscan2
- WDR47 | c.1706C>T p.S569L (on ENST00000369962 / NM_001142551.2; = p.S570L on NM_014969.5) | Missense Mutation (SNP) | VAF 64/139 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs140523650; called by muse, mutect2, varscan2
- AKAP9 | c.8676T>G p.C2892W (on ENST00000359028; = p.C2868W on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH18 | c.175C>A p.Q59K | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- DPP8 | c.1276A>G p.I426V (on ENST00000341861 / NM_001320875.2; = p.I410V on NM_017743.6) | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- EGR1 | c.250A>G p.S84G | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, varscan2
- HDAC5 | c.626A>G p.Q209R | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- IGLV4-69 | c.356T>A p.I119N | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- IGLV5-37 | c.32T>G p.L11R | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- LRP1 | c.7504A>G p.N2502D | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- MAGT1 | c.273-1G>C p.X91_splice (on ENST00000618282 / NM_001367916.1; = p.X123_splice on NM_032121.5) | Splice Site (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- NLGN1 | c.1006A>C p.K336Q | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NLRC5 | c.3083T>G p.L1028R | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2C3 | c.560A>C p.Q187P | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.383); called by muse, mutect2
- PIK3C2G | c.724A>G p.N242D | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- RBM28 | c.1595A>T p.H532L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.68); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- RC3H1 | c.2023_2042del p.V675Hfs*14 | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | called by mutect2, pindel, varscan2
- SP140 | c.1920G>T p.W640C | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- STRN4 | c.1741del p.L581Sfs*64 | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | called by mutect2, pindel, varscan2
- UGT1A4 | c.783del p.F261Lfs*2 | Frame Shift Del (DEL) | VAF 40/109 reads (37%) | called by mutect2, pindel, varscan2
- ZNF18 | c.839A>G p.K280R | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- ARAP2 | c.4719A>G p.A1573= | Silent (SNP) | VAF 57/132 reads (43%) | called by muse, mutect2, varscan2
- DISP3 | c.3756C>T p.C1252= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as rs202188597; called by mutect2, varscan2
- EGR1 | c.141G>A p.Q47= | Silent (SNP) | VAF 62/106 reads (58%) | catalogued as rs749068859, COSV99525214; called by muse, varscan2
- IGF2R | c.231C>T p.C77= | Silent (SNP) | VAF 38/78 reads (49%) | catalogued as rs140560792; called by muse, varscan2
- IGHV2-70 | c.339G>A p.T113= | Silent (SNP) | VAF 14/14 reads (100%) | catalogued as rs376111067; called by muse, varscan2
- IGHV2-70 | c.108C>G p.T36= | Silent (SNP) | VAF 24/24 reads (100%) | catalogued as rs371944329; called by muse, varscan2
- IGLC2 | c.195G>A p.K65= | Silent (SNP) | VAF 16/21 reads (76%) | catalogued as rs1803804; called by muse, mutect2, varscan2
- IGLV4-60 | c.81A>G p.Q27= | Silent (SNP) | VAF 54/129 reads (42%) | catalogued as rs767425929, COSV101135263; called by muse, varscan2
- KCNQ5 | c.1509A>G p.K503= | Silent (SNP) | VAF 70/77 reads (91%) | catalogued as rs1178834934, COSV100573030, COSV59661051; called by muse, mutect2, varscan2
- KRAS | c.180T>A p.G60= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs397517037, COSV55499291, COSV55523567, COSV99782811; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRT34 | c.96T>A p.L32= | Silent (SNP) | VAF 39/79 reads (49%) | called by muse, mutect2, varscan2
- LIMD2 | c.234C>T p.S78= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as rs1380154462; called by muse, mutect2, varscan2
- PTPRN2 | c.2103G>A p.P701= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs751000558; called by muse, mutect2, varscan2
- WDR27 | c.2124G>A p.R708= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs1467033876; called by muse, mutect2, varscan2
- ZNF835 | c.705G>A p.S235= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as COSV73379814; called by muse, mutect2, varscan2
- AC073310.1 | n.349G>A | RNA (SNP) | VAF 38/87 reads (44%) | catalogued as rs367926529; called by muse, mutect2, varscan2
- ADAMTS1 | c.*1070A>C | 3'UTR (SNP) | VAF 25/58 reads (43%) | called by muse, mutect2, varscan2
- AL591135.1 | n.5696C>T | RNA (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- BICC1 | c.*2265A>C | 3'UTR (SNP) | VAF 49/95 reads (52%) | called by muse, mutect2, varscan2
- CDC42BPA | c.*2348C>T | 3'UTR (SNP) | VAF 7/21 reads (33%) | catalogued as rs951427677; called by muse, mutect2, varscan2
- CLDN1 | c.*243T>A | 3'UTR (SNP) | VAF 11/16 reads (69%) | called by muse, mutect2, varscan2
- CLN8 | c.*2473G>A | 3'UTR (SNP) | VAF 48/82 reads (59%) | called by muse, mutect2, varscan2
- DSEL | c.*2536G>T | 3'UTR (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- FZD4 | c.*1137A>T | 3'UTR (SNP) | VAF 38/109 reads (35%) | catalogued as rs1051737581; called by muse, mutect2, varscan2
- GHR | c.*2356C>T | 3'UTR (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2, varscan2
- GPC1 | c.167-9569T>C | Intron (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2, varscan2
- KDM2A | c.*344C>A | 3'UTR (SNP) | VAF 26/49 reads (53%) | called by muse, mutect2, varscan2
- LMAN2 | c.*23T>A | 3'UTR (SNP) | VAF 66/138 reads (48%) | called by muse, mutect2, varscan2
- MAP3K20 | c.988-6105G>A | Intron (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- MBLAC2 | c.-104C>T | 5'UTR (SNP) | VAF 9/43 reads (21%) | catalogued as rs557665000; called by muse, mutect2, varscan2
- MFSD1 | c.163+76G>C | Intron (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- MYADM | chr19:53875589 C>T | 3'Flank (SNP) | VAF 4/8 reads (50%) | catalogued as COSV100425081; called by muse, varscan2
- MYO1A | c.1270-58G>T | Intron (SNP) | VAF 23/45 reads (51%) | called by muse, mutect2, varscan2
- PFKFB2 | c.*4375C>G | 3'UTR (SNP) | VAF 35/88 reads (40%) | called by muse, mutect2, varscan2
- RAB3IP | c.*3705G>A | 3'UTR (SNP) | VAF 46/102 reads (45%) | called by muse, mutect2, varscan2
- SESN3 | c.*6166C>G | 3'UTR (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- SNU13 | c.*146T>G | 3'UTR (SNP) | VAF 30/69 reads (43%) | called by muse, mutect2, varscan2
- TKFC | c.3+1566A>T | Intron (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- TMEM239 | c.*734G>A | 3'UTR (SNP) | VAF 33/64 reads (52%) | called by muse, mutect2, varscan2
- TNS3 | c.*1956T>C | 3'UTR (SNP) | VAF 4/55 reads (7%) | called by muse, mutect2
- TRNT1 | c.*494T>G | 3'UTR (SNP) | VAF 30/67 reads (45%) | called by muse, mutect2, varscan2
- WDFY3 | c.*1362T>C | 3'UTR (SNP) | VAF 3/50 reads (6%) | catalogued as rs1253410295; called by muse, mutect2
- ZBTB34 | c.*1893T>C | 3'UTR (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2, varscan2
- ZBTB40 | c.*2369A>T | 3'UTR (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2
